Somatic mutation profile of tumor specimen TCGA-IQ-A61H-01A (aliquot TCGA-IQ-A61H-01A-11D-A30E-08) from TCGA case TCGA-IQ-A61H, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 76.6 years (27,990 days).
Specimen TCGA-IQ-A61H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aca2464c-5710-41fb-a852-17bd500c0ff2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IQ-A61H-10A (Blood Derived Normal), aliquot TCGA-IQ-A61H-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a22a6df5-8b0c-4a08-896a-912e193820d9

The open-access MAF lists 143 somatic variants for this specimen: 106 protein-altering or splice-affecting, 36 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 36, Frame Shift Del 5, Nonsense Mutation 4, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACOT4 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.613); catalogued as rs375506372; called by muse, mutect2, varscan2
- AMER1 | c.2977A>T p.T993S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100365340; called by muse, mutect2, varscan2
- AMPH | c.2032G>C p.D678H | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57752548; called by muse, mutect2, varscan2
- ANGPTL2 | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV99400864; called by muse, mutect2, varscan2
- APBB1IP | c.796G>T p.V266L | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.293); catalogued as COSV100770877, COSV104424455; called by muse, mutect2, varscan2
- BBOF1 | c.1295T>C p.I432T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV100620804; called by muse, mutect2, varscan2
- CASR | c.2896G>A p.E966K (on ENST00000490131; = p.E1043K on NM_000388.4) | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as COSV99064811, COSV99948463; called by muse, mutect2, varscan2
- CES4A | c.1645C>G p.L549V (on ENST00000648724 / NM_001364782.1; = p.L451V on NM_001190201.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as COSV100109949; called by muse, mutect2
- CHD7 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs769161426, COSV101418001; called by muse, mutect2, varscan2
- CNTRL | c.3328G>C p.E1110Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99441178; called by muse, mutect2, varscan2
- CX3CL1 | c.1138C>A p.L380I | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.539); catalogued as COSV50057287; called by muse, mutect2, varscan2
- DCC | c.3797C>T p.P1266L | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.781); catalogued as rs912869366, COSV71427593, COSV71438411; called by muse, mutect2, varscan2
- DYNC2H1 | c.8065C>T p.Q2689* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as COSV100517573, COSV62090673; called by muse, mutect2
- DYTN | c.1360G>C p.E454Q | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV101510804; called by muse, mutect2, varscan2
- EAF2 | c.49C>G p.L17V | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV56545986, COSV99877376; called by muse, mutect2, varscan2
- EHBP1L1 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV100499659; called by muse, mutect2, varscan2
- EHBP1L1 | c.1251G>C p.E417D | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100499660; called by muse, mutect2, varscan2
- EHBP1L1 | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100499663; called by muse, mutect2, varscan2
- EHBP1L1 | c.2415G>T p.E805D | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.272); catalogued as COSV58572305; called by muse, mutect2, varscan2
- EHBP1L1 | c.2662G>T p.E888* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100499670; called by muse, mutect2, varscan2
- EHBP1L1 | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs774927469, COSV100499672; called by muse, mutect2, varscan2
- EVPL | c.4235T>A p.L1412Q | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100043979; called by muse, mutect2, varscan2
- FCRL5 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 45/282 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs746634732, COSV62513086; called by muse, mutect2, varscan2
- FGD2 | c.313A>C p.K105Q | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.154); catalogued as COSV99235856; called by muse, mutect2, varscan2
- GNPTAB | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.257); catalogued as CM094378, COSV100171690; called by mutect2, varscan2
- H2BC1 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.33); catalogued as rs747888176, COSV99219324; called by muse, mutect2, varscan2
- H4C2 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs1296621230, COSV55138254, COSV99774715, COSV99774982; called by muse, mutect2, varscan2
- HAPLN3 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as rs766473038, COSV100613601; called by muse, mutect2, varscan2
- HEPH | c.128G>A p.G43E (on ENST00000343002; = p.G97E on NM_138737.5) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); catalogued as COSV100294130; called by muse, mutect2, varscan2
- HSPA6 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.981); catalogued as COSV100553904; called by muse, mutect2, varscan2
- KCNA6 | c.992A>G p.N331S | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as COSV99768342; called by muse, mutect2, varscan2
- KCNQ3 | c.1306C>G p.R436G | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101195619, COSV66478081; called by muse, mutect2, varscan2
- KRT82 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as rs139996519, COSV99233615; called by muse, mutect2, varscan2
- LIMA1 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.066); catalogued as COSV100372218; called by muse, mutect2, varscan2
- LRRC4C | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs749349904, COSV99537028; called by muse, mutect2, varscan2
- MRPL50 | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV100879788; called by muse, mutect2, varscan2
- MYOM1 | c.691C>G p.Q231E | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as COSV99865309; called by muse, mutect2
- NAGA | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as rs1342256616, COSV101124135; called by muse, mutect2
- NALCN | c.2527G>C p.E843Q | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); catalogued as rs767624102, COSV51939083, COSV99213059; called by muse, mutect2, varscan2
- NAP1L1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV99673666; called by muse, mutect2, varscan2
- NBEA | c.4520T>C p.V1507A | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100076947; called by muse, mutect2, varscan2
- NFAT5 | c.3343C>G p.P1115A | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100590458; called by muse, mutect2, varscan2
- NLRP8 | c.1147G>C p.A383P | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as COSV99404735; called by muse, mutect2, varscan2
- NPR1 | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773838193, COSV100901963; called by muse, mutect2, varscan2
- OLFML1 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100206025, COSV100206222; called by muse, mutect2, varscan2
- OPA1 | c.2662-1G>A p.X888_splice (on ENST00000361510 / NM_130837.3; = p.X833_splice on NM_015560.3) | Splice Site (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100655157; called by muse, mutect2, varscan2
- OR10AG1 | c.443T>G p.I148S | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV100399982; called by muse, mutect2, varscan2
- OR2G2 | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100189579; called by muse, mutect2
- OR5I1 | c.743C>A p.T248N | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100041212; called by muse, mutect2
- OR8G2P | c.769T>C p.F257L | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as rs564897909; called by muse, mutect2, varscan2
- PDE1C | c.1732G>C p.G578R | Missense Mutation (SNP) | VAF 23/282 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100371071; called by muse, mutect2
- PDE2A | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100557657; called by muse, mutect2, varscan2
- PDZD2 | c.4663G>A p.A1555T | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV99223753; called by muse, mutect2, varscan2
- PLXNA3 | c.4229C>T p.S1410L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as COSV100859809; called by muse, mutect2, varscan2
- PPFIA2 | c.3172G>T p.D1058Y | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415510165, COSV100331722; called by muse, mutect2
- PREX1 | c.1522G>C p.E508Q | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.083); catalogued as COSV100906073; called by muse, mutect2, varscan2
- PRMT3 | c.938T>C p.I313T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100423658; called by muse, mutect2, varscan2
- PSPH | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV99304033; called by muse, mutect2, varscan2
- PTGIS | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV99720668; called by muse, mutect2, varscan2
- QKI | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.376); catalogued as COSV99274303, COSV99275474; called by muse, mutect2, varscan2
- RASGEF1B | c.800A>G p.Y267C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100020865; called by muse, mutect2, varscan2
- RPL18A | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99714350; called by muse, mutect2, varscan2
- SCN9A | c.3863C>T p.S1288F (on ENST00000303354; = p.S1277F on NM_002977.3) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57601215; called by muse, mutect2, varscan2
- SIN3A | c.2941G>C p.D981H | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs767869086, COSV100845038; called by muse, mutect2, varscan2
- SLC29A4 | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV51874075, COSV99786639; called by muse, mutect2, varscan2
- SLC34A3 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs768473327, COSV63186483; called by muse, mutect2, varscan2
- SMARCA4 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1060502063, COSV60791598; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ST3GAL6 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV54583495, COSV99504752; called by mutect2, varscan2
- STRA8 | c.286C>T p.H96Y (on ENST00000275764; = p.H74Y on NM_182489.2) | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV51963692, COSV99312248; called by muse, mutect2, varscan2
- SYNE4 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.074); catalogued as rs201815155, COSV99430838; called by muse, mutect2, varscan2
- SYT16 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs758851790, COSV70858745; called by muse, mutect2, varscan2
- TAPBP | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs374308480; called by muse, mutect2, varscan2
- TAS2R1 | c.80T>A p.I27N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101225697; called by muse, mutect2, varscan2
- TATDN2 | c.108C>G p.S36R | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV99813309; called by muse, mutect2
- TGDS | c.239C>G p.S80C | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as COSV54301303, COSV99724978; called by muse, mutect2, varscan2
- TGFBR2 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99846552; called by muse, mutect2, varscan2
- THAP7 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 48/678 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99301296; called by muse, mutect2
- TMEM121B | c.815C>A p.P272Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100082869, COSV100083432; called by muse, mutect2
- TPRKB | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV55541375; called by muse, mutect2, varscan2
- TRIM3 | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100624243; called by muse, mutect2, varscan2
- TRIO | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766016794, COSV100709891; called by muse, mutect2, varscan2
- TSPAN4 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.067); catalogued as rs373247920; called by muse, mutect2, varscan2
- TTC21A | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as rs201208359, COSV100086997; called by muse, mutect2, varscan2
- TTN | c.4678G>A p.E1560K (on ENST00000591111; = p.E1514K on NM_003319.4) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | PolyPhen probably damaging (0.994); catalogued as COSV100594895; called by muse, mutect2, varscan2
- UCHL5 | c.266C>G p.A89G | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100815281; called by muse, mutect2
- VPS13B | c.10603G>C p.D3535H | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100660892; called by muse, mutect2
- VPS45 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100964856; called by muse, varscan2
- WDR92 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99718167; called by muse, mutect2
- XRN1 | c.3460A>G p.I1154V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.626); catalogued as rs1412893692, COSV99377269; called by muse, mutect2, varscan2
- XRN1 | c.3076A>C p.K1026Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as COSV99377272; called by muse, mutect2, varscan2
- YRDC | c.798A>T p.Q266H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100203815; called by muse, mutect2, varscan2
- ZBED1 | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100585218; called by muse, mutect2, varscan2
- ZC3H4 | c.2809G>A p.V937M | Missense Mutation (SNP) | VAF 53/244 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); catalogued as rs368486156; called by muse, mutect2, varscan2
- ZFHX4 | c.1653C>G p.N551K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV99256482; called by muse, mutect2, varscan2
- ZFP30 | c.781C>G p.Q261E | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV100665754, COSV100665803; called by muse, mutect2, varscan2
- ZFYVE16 | c.4299C>G p.F1433L | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100566208; called by muse, mutect2
- ZNF335 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1374248469, COSV100532647; called by muse, mutect2, varscan2
- ZNF677 | c.10T>C p.S4P | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.276); catalogued as COSV100447787, COSV61721163; called by muse, mutect2, varscan2
- ZSWIM8 | c.3073A>G p.S1025G (on ENST00000605216 / NM_001242487.2; = p.S1030G on NM_015037.3) | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV101289801; called by muse, mutect2, varscan2
- BCLAF1 | c.758_759del p.S253Cfs*15 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by pindel, varscan2
- CACNA1E | c.4239_4242del p.F1413Lfs*20 | Frame Shift Del (DEL) | VAF 28/97 reads (29%) | called by mutect2, pindel, varscan2
- DNAJB4 | c.56_59del p.D19Vfs*36 | Frame Shift Del (DEL) | VAF 38/155 reads (25%) | called by mutect2, pindel, varscan2
- PCYT1B | c.740del p.D247Afs*3 | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | called by mutect2, pindel, varscan2
- TAS2R60 | c.752_753del p.S251Ffs*26 | Frame Shift Del (DEL) | VAF 13/110 reads (12%) | called by pindel, varscan2
- ADAP2 | c.654G>A p.G218= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV58295216; called by muse, mutect2, varscan2
- ARHGAP6 | c.1056G>C p.P352= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100272303; called by muse, mutect2, varscan2
- BVES | c.243C>A p.I81= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as COSV100114669; called by muse, mutect2, varscan2
- C1GALT1C1L | c.261G>A p.L87= | Silent (SNP) | VAF 15/156 reads (10%) | called by muse, mutect2, varscan2
- CACNA1S | c.450C>T p.A150= | Silent (SNP) | VAF 39/126 reads (31%) | catalogued as COSV100754661; called by muse, mutect2, varscan2
- CAND2 | c.2961G>A p.R987= (on ENST00000456430 / NM_001162499.2; = p.R894= on NM_012298.3) | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs979227092, COSV99928632; called by muse, mutect2, varscan2
- CSMD2 | c.2100C>A p.G700= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV53903699; called by muse, mutect2, varscan2
- CYP39A1 | c.93C>T p.C31= | Silent (SNP) | VAF 73/432 reads (17%) | catalogued as rs1407865086, COSV99241881; called by muse, mutect2, varscan2
- DPP4 | c.1962G>A p.A654= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs765615881, COSV100858698; called by muse, mutect2, varscan2
- EHBP1L1 | c.570G>A p.E190= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV100499656; called by muse, mutect2, varscan2
- EHBP1L1 | c.2322G>A p.L774= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100499667; called by muse, mutect2, varscan2
- FBN2 | c.240G>A p.Q80= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99325056; called by muse, mutect2, varscan2
- FNDC11 | c.153C>T p.F51= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV100918754; called by muse, mutect2, varscan2
- FYN | c.366C>T p.A122= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV99991156; called by muse, mutect2, varscan2
- GRB10 | c.238C>T p.L80= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV100239768; called by muse, mutect2, varscan2
- IL1B | c.195G>A p.A65= | Silent (SNP) | VAF 31/184 reads (17%) | catalogued as rs780676196, COSV54522250; called by muse, mutect2, varscan2
- KCNK4 | c.1029C>T p.N343= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as COSV100107654; called by muse, mutect2, varscan2
- LAMA5 | c.1728C>T p.P576= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs370141221; called by mutect2, varscan2
- MYH3 | c.5616G>A p.L1872= | Silent (SNP) | VAF 72/172 reads (42%) | catalogued as rs752145848, COSV99877737; called by muse, mutect2, varscan2
- NCDN | c.1758T>G p.L586= | Silent (SNP) | VAF 30/173 reads (17%) | catalogued as COSV100621901; called by muse, mutect2, varscan2
- OR14A16 | c.438T>A p.S146= | Silent (SNP) | VAF 16/210 reads (8%) | catalogued as COSV100713696; called by muse, mutect2
- PCMTD2 | c.198G>A p.P66= | Silent (SNP) | VAF 81/166 reads (49%) | catalogued as rs572183204, COSV55062921; called by muse, mutect2, varscan2
- PDE2A | c.1257G>A p.T419= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs376835526; called by muse, mutect2, varscan2
- PLCD1 | c.1986C>T p.G662= | Silent (SNP) | VAF 47/176 reads (27%) | catalogued as rs143935807; called by muse, mutect2, varscan2
- POM121C | c.2808G>A p.P936= (on ENST00000607367; = p.P694= on NM_001099415.3) | Silent (SNP) | VAF 13/148 reads (9%) | catalogued as rs782008939, COSV99992440; called by muse, mutect2, varscan2
- RNF123 | c.2055C>T p.L685= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100570248; called by muse, mutect2, varscan2
- SALL3 | c.1386C>T p.N462= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs1292225630, COSV101609937; called by muse, mutect2, varscan2
- SH3TC1 | c.2472C>T p.I824= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs529238778, COSV55283770; called by mutect2, varscan2
- SKI | c.1281G>A p.Q427= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV101049217; called by muse, mutect2
- SLC25A22 | c.654G>A p.A218= | Silent (SNP) | VAF 49/254 reads (19%) | catalogued as rs769899113, COSV57194024; ClinVar: likely benign; called by muse, mutect2, varscan2
- STAT5A | c.2121G>A p.V707= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99232410; called by muse, mutect2, varscan2
- SYNJ2 | c.4011G>A p.K1337= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV100840027; called by muse, mutect2, varscan2
- VILL | c.969G>A p.P323= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs746896524, COSV99378453; called by muse, mutect2, varscan2
- ZBTB1 | c.606T>C p.S202= | Silent (SNP) | VAF 27/157 reads (17%) | catalogued as COSV100703970; called by muse, mutect2, varscan2
- ZCWPW2 | c.291T>A p.P97= | Silent (SNP) | VAF 13/166 reads (8%) | catalogued as COSV101074533; called by muse, mutect2
- ZIM2 | c.522G>A p.E174= | Silent (SNP) | VAF 33/172 reads (19%) | catalogued as COSV99687375; called by muse, mutect2, varscan2
- PAQR6 | c.*236C>G | 3'UTR (SNP) | VAF 108/639 reads (17%) | catalogued as COSV99430745; called by muse, mutect2, varscan2
